Somatic mutation profile of tumor specimen MP2PRT-PASTDR-TMP1-A (aliquot MP2PRT-PASTDR-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASTDR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,205 days).
Specimen MP2PRT-PASTDR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 849587fa-a2aa-41a2-88ed-81888d8ed192.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASTDR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASTDR-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7a46472-58b4-449d-bd36-cd63c49dbdc1

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JTB | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV55132059; called by muse, mutect2
- KMT2A | c.5711C>G p.A1904G | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV63294888; called by muse, mutect2, varscan2
- MBNL1 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 95/368 reads (26%) | catalogued as COSV99221515; called by muse, mutect2, varscan2
- PCM1 | c.5848G>C p.E1950Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755641601; called by muse, mutect2, varscan2
- PPFIA2 | c.3605C>T p.P1202L | Missense Mutation (SNP) | VAF 118/360 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1385573646; called by muse, mutect2, varscan2
- SLC22A7 | c.440C>T p.A147V (on ENST00000372585 / NM_153320.2; = p.A145V on NM_006672.3) | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs370777342; called by muse, mutect2, varscan2
- TOGARAM1 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as COSV63896058; called by muse, mutect2, varscan2
- ZNF208 | c.2299C>T p.H767Y | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1279495576, COSV68106237, COSV68112056; called by muse, mutect2, varscan2
- ARHGAP31 | c.4035G>C p.Q1345H | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRCA2 | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CALR3 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2
- CCDC60 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DACH2 | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRRC69 | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRCAM | c.2207C>G p.S736C (on ENST00000379028 / NM_001371124.1; = p.S720C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PCDHA4 | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPA2 | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 119/318 reads (37%) | called by muse, mutect2, varscan2
- TSPAN32 | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 57/299 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- UBA2 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 78/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- USP34 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2
- FREM2 | c.6000C>T p.I2000= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as rs146568641, COSV54828137; called by muse, mutect2
- HTR3C | c.1122C>G p.L374= | Silent (SNP) | VAF 27/177 reads (15%) | called by muse, mutect2, varscan2
- SLC5A7 | c.1350G>T p.G450= | Silent (SNP) | VAF 32/310 reads (10%) | called by muse, mutect2, varscan2
- AL359922.1 | c.348-35130_348-35115delinsTTAGAGGG | Intron (DEL) | VAF 106/659 reads (16%) | called by pindel, varscan2*
